MMRF case MMRF_1560 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/35fdb692-1b15-46e8-ba32-a78f3068698f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.1 years (20,864 days); ISS stage: III; Days to last known disease status: 1,193 days (3.3 years); Days to last follow up: 1,193 days (3.3 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 25 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 5 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 5 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 87 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 44 days; Days to treatment end: 87 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 186 days; Days to treatment end: 264 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 274 days; Days to treatment end: 274 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 291 days; Days to treatment end: 291 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 325 days; Days to treatment end: 325 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -23 (ECOG 0): M Protein 2.8 g/dL; Immunoglobulin G 1.96 g/L; Immunoglobulin A 99.6 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 9.4 µg/mL; Hemoglobin 5.83 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.12 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 2.57 mmol/L; Calcium 2.38 mmol/L; Albumin 33 g/L; Total Protein 11.9 g/dL; Glucose 5.83 mmol/L.
- Day 61: Serum Free Immunoglobulin Light Chain, Kappa 0.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.53 mg/dL; Immunoglobulin G 3.09 g/L; Immunoglobulin A 6.96 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 76 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 1.98 mmol/L; Albumin 39 g/L; Total Protein 9.3 g/dL; Glucose 7.59 mmol/L.
- Day 170 (ECOG 1): Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 5.78 mmol/L.
- Day 236: Serum Free Immunoglobulin Light Chain, Kappa 0.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 3.68 g/L; Immunoglobulin A 6.5 g/L; Immunoglobulin M 0.25 g/L.
- Day 348: Hemoglobin 7.56 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.57 ×10⁹/L; Platelets 19 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 1.98 mmol/L; Glucose 5.56 mmol/L.
- Day 435: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 8.94 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.48 g/L; Beta 2 Microglobulin 0.69 µg/mL; Hemoglobin 9.11 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.29 ×10⁹/L; Platelets 251 ×10⁹/L.
- Day 530 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 7.98 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 9.18 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.08 mmol/L; Albumin 39.1 g/L; Total Protein 6.3 g/dL; Glucose 7.54 mmol/L.
- Day 607: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 7.69 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.84 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.08 mmol/L; Albumin 36.8 g/L; Total Protein 6.1 g/dL; Glucose 5.72 mmol/L.
- Day 691: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.58 mg/dL; Hemoglobin 8.68 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 5.5 mmol/L.
- Day 768: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 8.69 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 5.45 mmol/L.
- Day 859: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Hemoglobin 8.93 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 5.06 mmol/L.
- Day 950: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Hemoglobin 8.31 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 5.12 mmol/L.
- Day 1,053: Serum Free Immunoglobulin Light Chain, Kappa 4.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 1.59 g/L; Immunoglobulin M 0.36 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 0.6 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7.7 g/dL; Glucose 5.83 mmol/L.
- Day 1,095: Serum Free Immunoglobulin Light Chain, Kappa 5.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 1.87 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 6.4 g/dL; Glucose 5.34 mmol/L.
- Day 1,193: Serum Free Immunoglobulin Light Chain, Kappa 3.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Hemoglobin 8.87 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 5.72 mmol/L.

Other clinical attributes
- Day -23: Weight: 106 kg; Height: 193 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1560_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -23 days.
- Sample MMRF_1560_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -23 days.
